Gene-level copy-number profile of tumor specimen ALCH-B1MR-TTP1-A from ALCHEMIST case ALCH-B1MR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.6 years (28,721 days).
Specimen ALCH-B1MR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 54ef2025-b6f0-4669-ab0f-c2e59832d91e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1MR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/7801d1be-5a6d-4af2-b647-6109639867aa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 4,516; copy number 2: 53,397; copy number 3: 781; copy number 4: 81; copy number 5: 10; copy number 6: 3; copy number 7: 1; copy number 12: 3.

Homozygous deletions (total copy number 0; autosomes only): 66 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,712,200–3,714,298, 1 gene (within-gene range 0–1): TP73-AS2.
- chr1:16,043,736–16,057,308, 1 gene: CLCNKB.
- chr2:61,710,076–61,710,978, 1 gene: AC108039.1.
- chr3:46,979,666–47,009,704, 1 gene (within-gene range 0–3): NBEAL2.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr4:1,986,384–1,986,477, 1 gene (within-gene range 0–2): MIR943.
- chr4:3,441,968–3,449,486, 1 gene: HGFAC.
- chr4:8,269,754–8,307,098, 1 gene: HTRA3.
- chr7:105,532,169–105,567,677, 1 gene (within-gene range 0–2): RINT1.
- chr8:7,190,901–7,191,563, 1 gene: RPS3AP33.
- chr8:22,578,279–22,602,084, 2 genes (within-gene range 0–2): PDLIM2, AC037459.1.
- chr8:27,490,781–27,545,564, 1 gene: EPHX2.
- chr10:133,230,217–133,247,891, 4 genes: UTF1, VENTX, MIR202HG, MIR202.
- chr11:1,049,880–1,055,749, 1 gene: LINC02688.
- chr11:1,983,237–1,989,920, 1 gene (within-gene range 0–1): MRPL23-AS1.
- chr12:132,136,594–132,152,473, 2 genes: DDX51, NOC4L.
- chr15:85,272,527–85,272,974, 1 gene (within-gene range 0–2): AC044860.3.
- chr16:1,065,240–1,066,502, 1 gene (within-gene range 0–1): AC009041.2.
- chr16:1,431,078–1,444,556, 3 genes: PERCC1, CCDC154, AL032819.2.
- chr16:1,445,343–1,452,653, 2 genes (within-gene range 0–2): AL031600.3, AL031600.1.
- chr16:1,770,286–1,781,708, 3 genes (within-gene range 0–2): NME3, MRPS34, EME2.
- chr16:1,790,413–1,794,971, 1 gene (within-gene range 0–1): IGFALS.
- chr16:2,088,708–2,135,898, 2 genes (within-gene range 0–1): PKD1, MIR1225.
- chr16:2,106,669–2,136,129, 6 genes: MIR6511B1, AC009065.6, AC009065.3, Y_RNA, MIR4516, MIR3180-5.
- chr16:15,125,242–15,157,020, 5 genes (within-gene range 0–2): PKD1P6, MIR6511B2, Y_RNA, MIR3180-4, AC126763.1.
- chr16:56,932,142–56,944,864, 3 genes: HERPUD1, AC012181.2, AC012181.1.
- chr17:75,818,815–75,820,055, 1 gene (within-gene range 0–2): AC087289.1.
- chr17:83,079,609–83,106,910, 3 genes: METRNL, AC130371.2, AC144831.1.
- chr19:6,393,794–6,412,404, 1 gene (within-gene range 0–2): AC011491.1.
- chr19:7,903,843–7,914,478, 2 genes: MAP2K7, AC010336.4.
- chr19:7,924,491–7,926,810, 2 genes (within-gene range 0–2): CTXN1, AC010336.5.
- chr20:63,939,829–63,956,985, 4 genes (within-gene range 0–2): UCKL1, MIR1914, MIR647, UCKL1-AS1.
- chr22:43,212,674–43,213,661, 1 gene (within-gene range 0–2): SCUBE1-AS2.
- chr22:50,274,979–50,327,012, 4 genes (within-gene range 0–1): PLXNB2, DENND6B, CR559946.1, CR559946.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:65,189,995–65,230,861, 3 genes, copy number 5: BMS1P12, AL512605.1, AL512605.2.
- chr9:65,287,914–65,323,015, 1 gene, copy number 7: CBWD4P.
- chr10:79,825,902–79,827,602, 1 gene, copy number 5 (within-gene range 3–5): AL135925.1.
- chr11:68,707,440–68,751,520, 1 gene, copy number 5: TESMIN.
- chr15:74,719,542–74,725,536, 1 gene, copy number 6: CYP1A1.
- chr20:57,351,223–57,379,211, 3 genes, copy number 5: RAE1, MTND1P9, MTRNR2L3.
- chr21:44,217,014–44,262,216, 5 genes, copy number 6–12: ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.

Autosomal genes at a single copy (total copy number 1): 1,720. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
